CPTAC case C3L-08279 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00b8b287-f156-4104-a476-16b69c9e6d91

Demographics
Sex at birth: female; Race: white; Year of birth: 1948; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 73.7 years (26,924 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N3a; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 44 days; Days to last follow up: 44 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 14; Lymph nodes tested: 23.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 43 days; Days to treatment end: 141 days; Treatment outcome: Partial Response.

Follow-up (2 entries)
- Days to follow up: 409 days (1.1 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Follow-up contact recording only the day: day 44.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08279-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 113 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08279-22: Section location: Stomach, NOS; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample C3L-08279-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 92 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08279-23: Section location: Stomach, NOS; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-08279-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
